CCDI case PBBSCK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Base of tongue.
https://portal.gdc.cancer.gov/cases/ba7c009b-aae8-4912-85f3-ad2e32191a21

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Base of tongue, NOS; Age at diagnosis: 16.2 years (5,919 days).

Biospecimens (3 samples)
- Sample 0DFXEY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFXFA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFXGZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
